Somatic mutation profile of tumor specimen ALCH-B5FY-TTP1-A (aliquot ALCH-B5FY-TTP1-A-1-0-D-A83F-36) from ALCHEMIST case ALCH-B5FY, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 57.9 years (21,153 days).
Specimen ALCH-B5FY-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 63aea2b7-ffd1-4adc-8e4a-f7f13a45e59f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B5FY-NB1-A (Blood Derived Normal), aliquot ALCH-B5FY-NB1-A-1-0-D-A83F-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/76095fa6-5c8f-4a74-9689-c43e197de659

The open-access MAF lists 4 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, 5'Flank 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NAIP | c.367G>C p.D123H | Missense Mutation (SNP) | VAF 14/334 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0.007); called by muse, mutect2
- TMEM168 | c.1726G>C p.D576H | Missense Mutation (SNP) | VAF 24/400 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2
- DOCK3 | c.5796C>T p.Y1932= | Silent (SNP) | VAF 14/384 reads (4%) | catalogued as rs782286280; called by muse, mutect2
- POLR1B | chr2:112542463 G>A | 5'Flank (SNP) | VAF 36/304 reads (12%) | catalogued as rs374096069, COSV51976088; called by muse, mutect2, varscan2
